Gene-level copy-number profile of tumor specimen TCGA-OR-A5JA-01A from TCGA case TCGA-OR-A5JA, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 53.2 years (19,436 days).
Specimen TCGA-OR-A5JA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.586958fe-f0d2-466d-be89-af58aea6dc2c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5488e35f-1932-47c7-a5f9-4af14821cb8a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 212; copy number 3: 20,962; copy number 4: 9,150; copy number 5: 1,455; copy number 6: 10,954; copy number 7: 10,549; copy number 8: 6,120; copy number 9: 374; copy number 10: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JA-01A-11D-A29H-01): tumor purity 0.75, ploidy 5.52, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:15,021,553–15,619,819, 5 genes: RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 14,659 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:28,435,449–43,972,184, 185 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).
- chr5:58,198–147,782,775, 2,323 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr6:167,607–40,000,527, 1,165 genes, copy number 7–10 (broad region; genes not listed).
- chr7:70,972–64,300,818, 1,161 genes, copy number 7 (broad region; genes not listed).
- chr7:130,018,287–159,233,377, 674 genes, copy number 7–8 (broad region; genes not listed).
- chr12:66,767–124,316,024, 2,796 genes, copy number 7–9 (broad region; genes not listed).
- chr14:18,333,726–24,576,250, 469 genes, copy number 8 (broad region; genes not listed).
- chr15:19,878,555–47,134,122, 862 genes, copy number 7 (broad region; genes not listed).
- chr15:47,272,597–47,399,554, 4 genes, copy number 7: RN7SKP139, AC084882.1, AC023905.1, AC009558.1.
- chr16:5,239,802–7,713,340, 1 gene, copy number 7 (within-gene range 6–7): RBFOX1.
- chr16:5,596,856–90,222,851, 2,155 genes, copy number 7 (broad region; genes not listed).
- chr19:1,815,248–58,605,223, 2,864 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
